Somatic mutation profile of tumor specimen TARGET-20-PASRJL-09A (aliquot TARGET-20-PASRJL-09A-01D) from TARGET case TARGET-20-PASRJL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,867 days).
Specimen TARGET-20-PASRJL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a24315e1-0e67-49b7-972a-3671a152bb41.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASRJL-14A (Bone Marrow Normal), aliquot TARGET-20-PASRJL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffe9c949-6f3a-406d-8175-35b0b94bb3cd

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 41/211 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.5800G>A p.V1934M | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52373704; called by muse, mutect2, varscan2
